Gene-level copy-number profile of tumor specimen TCGA-D8-A1XV-01A from TCGA case TCGA-D8-A1XV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 84.4 years (30,830 days).
Specimen TCGA-D8-A1XV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.1fa10a5d-7fc9-4a26-9251-bade7c2cbf13.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1XV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/186d53dc-630b-4a10-bc5c-cce0331d9605

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 83; copy number 1: 13,187; copy number 2: 43,925; copy number 5: 21; copy number 7: 2,604.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1XV-01A-11D-A14J-01): tumor purity 0.69, ploidy 2.07, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 83 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:131,639,396–133,214,832, 83 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,625 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 7 (broad region; genes not listed).
- chr12:129,013,336–130,165,740, 21 genes, copy number 5: NLRP9P1, TMEM132D, TMEM132D-AS1, AC107033.1, TMEM132D-AS2, AC079456.1, AC130404.1, AC130404.2, AC117373.1, AC117373.2, AC055717.3, AC055717.1, AC055717.2, LINC02418, AC135388.1, LINC02419, AC026336.4, AC026336.3, FZD10-AS1, AC026336.5, FZD10.

Autosomal genes at a single copy (total copy number 1): 10,766. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
